Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A4QT, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A4QT-01A (Primary Tumor).

Gross Description: There is a part of esophagus 9x7 cm in size, with tumor up to 7 cm in size, with ulceration.

Microscopic Description: Squamous carcinoma of the esophagus, keratinizing type, G-2, pT3. One examined periesophageal lymph node and seventeen examined gastric lymph node demonstrated follicular hyperplasia.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Adventitia, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Esophagectomy

Tumor site: Thoracic esophagus

Tumor size: 0 x 0 x 7 cm

Histologic type: Squamous cell carcinoma, keratinizing

Histologic grade: Moderately differentiated

Tumor extent: Adventitia

Lymph nodes: 0/17 positive for metastasis (Paraesophageal, gastric lymph nodes. 0/17)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-0-3
carcinoma, squamous cell, keratinizing, NOS
8071/3

Site: esophagus, thoracic C15.1

lw
10/23/12

Source: NCI Genomic Data Commons file ea0c52f7-2a62-4d69-a2d3-4ab76abecc50 (TCGA-IG-A4QT.BF8D6216-D19C-45B7-81CA-4E0F4B53A3A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).